CCDI case PBBZHZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/f38ffbac-ea23-4e27-a17c-dcca22b67de6

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Synovial sarcoma, biphasic: ICD-O-3 morphology code: 9043/3; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 16.1 years (5,871 days).

Biospecimens (3 samples)
- Sample 0DM8U2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DM8UA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DM8VU: Tissue type: Tumor; Specimen type: Solid Tissue.
